MMRF case MMRF_1889 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/851f305b-e03c-4648-9400-facaa7123cc6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Dead; Days to death: 836 days (2.3 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.3 years (22,773 days); ISS stage: III; Days to last known disease status: 836 days (2.3 years); Days to last follow up: 836 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 139 days; Days to treatment end: 140 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 142 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 266 days; Days to treatment end: 421 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 421 days (1.2 years); Days to treatment end: 519 days (1.4 years).
   Treatment given: Therapeutic agents: Carfilzomib + Thalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 519 days (1.4 years); Days to treatment end: 554 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 519 days (1.4 years); Days to treatment end: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Bendamustine; Regimen or line of therapy: Third line of therapy; Days to treatment start: 557 days (1.5 years); Days to treatment end: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 659 days (1.8 years); Days to treatment end: 800 days (2.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 659 days (1.8 years); Days to treatment end: 687 days (1.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 687 days (1.9 years); Days to treatment end: 800 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26: M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 58.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 73.5 g/L; Immunoglobulin A 0.286 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 10.2 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.36 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 139 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 29 g/L; Total Protein 11.3 g/dL; Glucose 7.48 mmol/L; C-Reactive Protein 0.34 mg/dL.
- Day 64 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL; Immunoglobulin G 8.18 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 357 ×10⁹/L; Creatinine 185 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 7.59 mmol/L.
- Day 160 (ECOG 1): Lactate Dehydrogenase 5.65 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.02 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 246 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 8.69 mmol/L.
- Day 253 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.94 mmol/L.
- Day 344 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.55 mmol/L.
- Day 435 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 26.6 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 8 g/dL; Glucose 6.88 mmol/L.
- Day 526 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 33.6 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 74 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 8.7 g/dL; Glucose 7.59 mmol/L.
- Day 610 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 22.8 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 5.28 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 342 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 8.1 g/dL; Glucose 5.67 mmol/L.
- Day 687 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 202 µmol/L; Blood Urea Nitrogen 21.1 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 13.5 mmol/L.
- Day 785 (ECOG 2): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 179 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 36.1 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.44 µg/mL; Lactate Dehydrogenase 11.5 µkat/L; Hemoglobin 4.15 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 17 ×10⁹/L; Creatinine 571 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.18 mmol/L; Albumin 21 g/L; Total Protein 8.1 g/dL; Glucose 5.56 mmol/L.
- Day 836: Immunoglobulin G 30.3 g/L; Hemoglobin 3.22 mmol/L; Leukocytes 0.2 ×10⁹/L; Absolute Neutrophil 0 ×10⁹/L; Platelets 3 ×10⁹/L; Creatinine 33.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 1.98 mmol/L; Albumin 11 g/L; Total Protein 4.6 g/dL; Glucose 2.86 mmol/L.

Other clinical attributes
- Day -26: Weight: 96 kg; Height: 155 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1889_2_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_1889_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
- Sample MMRF_1889_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 435 days (1.2 years).
